Somatic mutation profile of tumor specimen 0DMRBD from CCDI case PBBYSF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.3 years (2,683 days).
Specimen 0DMRBD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8537a6b5-d75b-4866-9ec9-380eaf2e8b70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMRAO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a731f80f-7d8d-4e6b-9386-0b1e674ca0ef

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 594/1181 reads (50%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 54/852 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2
- ADAM28 | c.227+4_227+7del p.X76_splice | Splice Site (DEL) | VAF 240/734 reads (33%) | catalogued as rs746369536; called by pindel, varscan2
- ARMC10 | c.845C>T p.T282M | Missense Mutation (SNP) | VAF 210/2804 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs150955727; called by muse, mutect2
- CHML | c.1588T>C p.F530L | Missense Mutation (SNP) | VAF 310/2178 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.879); catalogued as rs375203343; called by muse, mutect2, varscan2
- GABRQ | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 51/1290 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs782699208, COSV64782303; called by muse, mutect2
- LTBP2 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 231/281 reads (82%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs762006320, COSV56210216; called by muse, mutect2, varscan2
- OR10J1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 558/1640 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.045); catalogued as COSV101419881; called by muse, mutect2, varscan2
- ZBTB34 | c.1411G>A p.V471M | Missense Mutation (SNP) | VAF 156/1115 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); catalogued as rs772560493, COSV59860356; called by muse, mutect2, varscan2
- ZEB2 | c.3214C>A p.Q1072K | Missense Mutation (SNP) | VAF 856/1704 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57951889; called by muse, mutect2, varscan2
- CXCR3 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 144/402 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DGKK | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 273/682 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FLG2 | c.2861G>A p.G954D | Missense Mutation (SNP) | VAF 112/2621 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.466); called by muse, mutect2
- NKAIN2 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 264/1109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TBX18 | c.1140T>A p.N380K | Missense Mutation (SNP) | VAF 109/2181 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.035); called by muse, mutect2
- TP53BP1 | c.2623C>G p.L875V | Missense Mutation (SNP) | VAF 73/1192 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- CXCR3 | c.237G>T p.L79= | Silent (SNP) | VAF 68/742 reads (9%) | called by muse, mutect2
- EPRS1 | c.2985T>G p.G995= | Silent (SNP) | VAF 64/1751 reads (4%) | called by muse, mutect2
- PCDHGA4 | c.2280C>A p.G760= | Silent (SNP) | VAF 73/1328 reads (5%) | catalogued as COSV54015292; called by muse, mutect2
- DEPDC5 | c.624+10T>C | Intron (SNP) | VAF 21/644 reads (3%) | called by muse, mutect2
- PGGT1B | c.140+65A>T | Intron (SNP) | VAF 72/574 reads (13%) | called by muse, mutect2, varscan2
